Somatic mutation profile of tumor specimen TCGA-35-5375-01A (aliquot TCGA-35-5375-01A-01D-1625-08) from TCGA case TCGA-35-5375, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 62.0 years (22,628 days).
Specimen TCGA-35-5375-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 148d11f3-a276-4c00-a261-767cf195309c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-35-5375-10A (Blood Derived Normal), aliquot TCGA-35-5375-10A-01D-1625-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7d7063a3-af4b-48bf-b6ac-d1221d7ca1d4

The open-access MAF lists 457 somatic variants for this specimen: 355 protein-altering or splice-affecting, 91 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 299, Silent 91, Nonsense Mutation 25, Splice Site 13, Intron 7, Frame Shift Del 6, Splice Region 5, Frame Shift Ins 4, RNA 3, In Frame Del 3, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 27/39 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AACS | c.1828G>T p.G610C | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.524); catalogued as COSV55539827; called by muse, mutect2, varscan2
- AC011448.1 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs758935454, COSV99364153, COSV99364527; called by muse, mutect2, varscan2
- ACSM2B | c.1715G>T p.G572V | Missense Mutation (SNP) | VAF 128/270 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as COSV61659635; called by muse, mutect2, varscan2
- ACTRT1 | c.979C>G p.P327A | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.024); catalogued as COSV64419923; called by muse, mutect2, varscan2
- ADCY10 | c.2171+1G>A p.X724_splice | Splice Site (SNP) | VAF 49/111 reads (44%) | catalogued as rs756985055, COSV63239101; called by muse, mutect2, varscan2
- ADCY5 | c.3688G>A p.A1230T | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.062); catalogued as COSV59203141; called by muse, mutect2, varscan2
- ADGRG4 | c.8802G>T p.M2934I | Missense Mutation (SNP) | VAF 75/101 reads (74%) | SIFT tolerated (0.12); PolyPhen benign (0.087); catalogued as COSV54964751, COSV54970212; called by muse, mutect2, varscan2
- AGMO | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61105683, COSV61124079; called by muse, mutect2, varscan2
- AHDC1 | c.3983C>G p.S1328* | Nonsense Mutation (SNP) | VAF 10/66 reads (15%) | catalogued as COSV55941787; called by muse, mutect2, varscan2
- ALDH8A1 | c.1460A>T p.H487L | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV55643864; called by muse, mutect2, varscan2
- ALS2 | c.3703G>T p.G1235* | Nonsense Mutation (SNP) | VAF 17/54 reads (31%) | catalogued as COSV51891773; called by muse, mutect2, varscan2
- ANKFN1 | c.1949G>T p.R650I | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV59457654; called by muse, mutect2, varscan2
- ANKS1B | c.1733A>C p.K578T | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.018); catalogued as COSV61355394, COSV61371101; called by muse, mutect2, varscan2
- ANO4 | c.1260C>A p.H420Q (on ENST00000392977 / NM_001286615.2; = p.H385Q on NM_178826.4) | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs140890653, COSV54609879; called by muse, mutect2, varscan2
- ARHGAP11B | c.320G>C p.G107A | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as COSV101451740; called by mutect2, varscan2
- ASAP1 | c.518A>G p.Y173C | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63053569; called by muse, mutect2, varscan2
- ASCC2 | c.159G>T p.E53D | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.179); catalogued as COSV57076218; called by muse, mutect2, varscan2
- ATG13 | c.459-2A>G p.X153_splice | Splice Site (SNP) | VAF 30/72 reads (42%) | catalogued as COSV56321657; called by muse, mutect2, varscan2
- ATP13A5 | c.2574G>C p.L858F | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60873991; called by muse, mutect2, varscan2
- BBX | c.936G>T p.M312I | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100362368, COSV57892870; called by muse, mutect2, varscan2
- BDP1 | c.4939C>G p.Q1647E | Missense Mutation (SNP) | VAF 38/55 reads (69%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV62434014; called by muse, mutect2, varscan2
- BIRC6 | c.2471A>G p.Y824C | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs776144854, COSV70204462; called by muse, mutect2, varscan2
- BPNT2 | c.959G>T p.G320V | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52908791; called by muse, mutect2, varscan2
- BZW1 | c.742C>T p.Q248* | Nonsense Mutation (SNP) | VAF 20/46 reads (43%) | catalogued as COSV100729806; called by muse, mutect2, varscan2
- C3orf56 | c.395T>C p.M132T | Missense Mutation (SNP) | VAF 71/264 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs745746319, COSV101228910; called by muse, mutect2, varscan2
- CACNA1E | c.891T>A p.F297L | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV62406200, COSV62414375; called by muse, mutect2, varscan2
- CAPN11 | c.2034C>G p.N678K | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.617); catalogued as COSV67239150; called by muse, mutect2, varscan2
- CAV3 | c.206A>T p.K69M | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1447903804, COSV100372997, COSV57480710; called by muse, mutect2, varscan2
- CBLC | c.1391C>G p.A464G | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV54325440; called by muse, mutect2, varscan2
- CCDC80 | c.1849G>T p.G617W | Missense Mutation (SNP) | VAF 103/248 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV52819414; called by muse, mutect2, varscan2
- CCL25 | c.269T>A p.L90Q | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53664937; called by muse, mutect2, varscan2
- CDH11 | c.2355G>C p.L785F | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51774340; called by muse, mutect2, varscan2
- CDH18 | c.2161G>T p.A721S | Missense Mutation (SNP) | VAF 59/103 reads (57%) | SIFT tolerated (0.55); PolyPhen benign (0.134); catalogued as COSV56936228, COSV56953994; called by muse, mutect2, varscan2
- CDH23 | c.8339A>T p.Q2780L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV56484918; called by muse, mutect2, varscan2
- CDH6 | c.1392T>G p.N464K | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.515); catalogued as COSV54076740; called by muse, mutect2, varscan2
- CDK5RAP2 | c.3046G>T p.A1016S | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (0.42); PolyPhen benign (0.355); catalogued as COSV62577393; called by muse, mutect2, varscan2
- CDK6 | c.609G>T p.W203C | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99720489; called by muse, mutect2, varscan2
- CDK6 | c.608G>C p.W203S | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99720492; called by muse, mutect2, varscan2
- CENPF | c.5952G>A p.M1984I | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.557); catalogued as COSV65278431; called by muse, mutect2, varscan2
- CFAP251 | c.2116C>T p.Q706* | Nonsense Mutation (SNP) | VAF 15/123 reads (12%) | catalogued as rs777880480, COSV56614839; called by muse, mutect2, varscan2
- CFAP47 | c.5144G>T p.R1715L | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV57971771, COSV57976184; called by muse, mutect2, varscan2
- CFAP54 | c.8115G>T p.W2705C | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61574704; called by muse, mutect2, varscan2
- CFHR4 | c.68G>T p.C23F (on ENST00000367416 / NM_001201551.2; = p.C24F on NM_006684.5) | Missense Mutation (SNP) | VAF 62/112 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV52234646; called by muse, varscan2
- CHD7 | c.8623G>T p.G2875C | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); catalogued as COSV71113823; called by muse, mutect2, varscan2
- CHIT1 | c.362A>T p.N121I | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.706); catalogued as COSV55149430; called by muse, mutect2, varscan2
- CHN1 | c.470A>G p.Y157C | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.155); catalogued as rs772160492, COSV69298178; called by muse, mutect2, varscan2
- CHTF18 | c.1861G>A p.D621N | Missense Mutation (SNP) | VAF 42/50 reads (84%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV50210923; called by muse, mutect2, varscan2
- CILP2 | c.2302G>T p.A768S | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.65); PolyPhen benign (0.048); catalogued as COSV52276460, COSV99364160; called by mutect2, varscan2
- CLDN14 | c.518T>A p.L173H | Missense Mutation (SNP) | VAF 35/44 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59776946; called by muse, mutect2, varscan2
- CLEC4F | c.718G>T p.A240S | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as COSV99713425; called by muse, mutect2, varscan2
- CLEC4F | c.717G>C p.Q239H | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV99713431; called by muse, mutect2, varscan2
- CLSTN2 | c.2551G>T p.G851C | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71724246; called by muse, mutect2, varscan2
- CNTNAP5 | c.1337A>T p.N446I | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV70507714; called by muse, mutect2, varscan2
- COL11A1 | c.2503G>T p.G835* | Nonsense Mutation (SNP) | VAF 6/23 reads (26%) | catalogued as COSV62176731, COSV62194459; called by muse, mutect2, varscan2
- COL11A2 | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.723); catalogued as COSV100553227; called by muse, mutect2, varscan2
- COL12A1 | c.2665T>A p.S889T | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as COSV59405546; called by muse, varscan2
- COL19A1 | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100504669; called by muse, mutect2, varscan2
- COL1A2 | c.988C>A p.P330T | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.638); catalogued as COSV51964459; called by muse, mutect2, varscan2
- COL20A1 | c.2690C>A p.P897Q | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV58925725; called by muse, mutect2, varscan2
- COL4A2 | c.2800C>A p.P934T | Missense Mutation (SNP) | VAF 89/150 reads (59%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.867); catalogued as COSV64632971; called by muse, mutect2, varscan2
- COL4A4 | c.2090C>A p.P697H | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV61635748; called by muse, mutect2, varscan2
- CPXM2 | c.1725C>A p.F575L | Missense Mutation (SNP) | VAF 22/29 reads (76%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV53869378; called by muse, mutect2, varscan2
- CSNK1A1L | c.958C>A p.Q320K | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.334); catalogued as COSV65790103; called by muse, mutect2, varscan2
- CSTF3 | c.1586A>G p.K529R | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.091); catalogued as COSV60613931; called by muse, mutect2, varscan2
- CTCF | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 27/37 reads (73%) | SIFT tolerated (0.1); PolyPhen benign (0.082); catalogued as COSV50468532, COSV50506305; called by muse, mutect2, varscan2
- CXXC5 | c.766G>A p.G256S | Missense Mutation (SNP) | VAF 57/79 reads (72%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs774217585, COSV100210471; called by muse, mutect2, varscan2
- CYP26B1 | c.1069G>A p.V357I | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as rs541205721, COSV50014098; called by muse, mutect2, varscan2
- CYP4F3 | c.754G>T p.D252Y | Missense Mutation (SNP) | VAF 67/112 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as COSV55409781, COSV55413113; called by muse, mutect2, varscan2
- DAXX | c.2212G>C p.D738H | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56472109; called by muse, mutect2
- DDR2 | c.739G>T p.E247* | Nonsense Mutation (SNP) | VAF 31/62 reads (50%) | catalogued as COSV63370732, COSV63372094, COSV63373794; called by muse, mutect2, varscan2
- DENND4C | c.5585A>C p.E1862A (on ENST00000434457 / NM_001330640.2; = p.E1813A on NM_017925.7) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); catalogued as COSV63009679; called by muse, varscan2
- DIDO1 | c.473G>T p.G158V | Missense Mutation (SNP) | VAF 58/82 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56632303; called by muse, mutect2, varscan2
- DMXL2 | c.8971C>T p.R2991* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as rs775750727, COSV51840432; called by muse, varscan2
- DMXL2 | c.8951A>T p.H2984L | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51854289; called by muse, varscan2
- DNAH5 | c.6178A>T p.K2060* | Nonsense Mutation (SNP) | VAF 28/77 reads (36%) | catalogued as COSV54246958; called by muse, mutect2, varscan2
- DNAH7 | c.9047G>C p.S3016T | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.69); PolyPhen benign (0.012); catalogued as COSV56781275; called by muse, mutect2, varscan2
- DNAH8 | c.2130+2T>C p.X710_splice | Splice Site (SNP) | VAF 7/36 reads (19%) | catalogued as COSV59474600; called by muse, mutect2
- DNAJC13 | c.434A>C p.N145T | Missense Mutation (SNP) | VAF 48/83 reads (58%) | SIFT tolerated (0.17); PolyPhen benign (0.173); catalogued as COSV53456474; called by muse, mutect2, varscan2
- DSG4 | c.2727G>C p.E909D | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs755092274, COSV57396495; called by muse, mutect2, varscan2
- DTNA | c.520G>T p.V174F | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52021625; called by muse, mutect2, varscan2
- DYNC1H1 | c.12687C>T p.G4229= | Splice Region (SNP) | VAF 4/42 reads (10%) | catalogued as rs994411940, COSV64141280; called by muse, mutect2
- DZIP3 | c.964A>C p.M322L | Missense Mutation (SNP) | VAF 10/157 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV64311886, COSV64313531; called by muse, mutect2
- EIF4G1 | c.2619G>A p.T873= (on ENST00000346169 / NM_198241.3; = p.T678= on NM_004953.5) | Splice Region (SNP) | VAF 8/46 reads (17%) | catalogued as rs971962143, COSV59993368; called by mutect2, varscan2
- EIF5 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV99384597; called by muse, mutect2, varscan2
- EIPR1 | c.836G>T p.R279L | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV66132501; called by muse, mutect2, varscan2
- ELOA2 | c.1795C>G p.Q599E | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.127); catalogued as rs1461513599, COSV55307001; called by muse, mutect2, varscan2
- EPHA5 | c.881G>C p.G294A | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56659351, COSV56668188; called by muse, mutect2, varscan2
- EPHB2 | c.1168G>T p.E390* | Nonsense Mutation (SNP) | VAF 19/58 reads (33%) | catalogued as COSV65865760; called by muse, mutect2, varscan2
- EPN2 | c.772T>A p.S258T | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV100127254; called by muse, mutect2, varscan2
- ERICH3 | c.4171G>T p.D1391Y | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); catalogued as COSV58615904; called by muse, mutect2, varscan2
- ERN2 | c.202C>A p.P68T | Missense Mutation (SNP) | VAF 87/191 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56835716, COSV56836967; called by muse, mutect2, varscan2
- ESR1 | c.1652C>A p.A551E | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.329); catalogued as COSV52792574, COSV52800121; called by muse, mutect2, varscan2
- F2R | c.793G>T p.G265C | Missense Mutation (SNP) | VAF 48/73 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100058220; called by muse, mutect2, varscan2
- FAM120A | c.2981T>G p.I994S | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.948); catalogued as COSV52909677; called by muse, mutect2, varscan2
- FAM135B | c.3683T>A p.L1228H | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52748482; called by muse, mutect2, varscan2
- FAM83B | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 76/137 reads (55%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.489); catalogued as COSV60925973; called by muse, mutect2, varscan2
- FANCD2OS | c.113G>C p.C38S | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV67559237; called by muse, mutect2, varscan2
- FANCM | c.1778G>C p.R593P | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.505); catalogued as COSV57505503; called by muse, mutect2, varscan2
- FAP | c.538C>A p.P180T | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV51866616; called by muse, mutect2, varscan2
- FAT2 | c.3151G>A p.V1051M | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55827712; called by muse, mutect2, varscan2
- FBXO43 | c.619G>C p.V207L | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV101413751; called by muse, mutect2
- FCRL1 | c.245G>T p.G82V | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV63826995; called by muse, mutect2, varscan2
- FCRL2 | c.344C>A p.S115Y | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as COSV63833574, COSV63834930; called by muse, mutect2, varscan2
- FCRL3 | c.1606A>T p.T536S | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.326); catalogued as COSV63844353; called by muse, mutect2, varscan2
- FH | c.1409A>G p.K470R | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.29); catalogued as COSV63818834; called by muse, mutect2, varscan2
- FOXB1 | c.132G>C p.M44I | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV101249614; called by muse, mutect2, varscan2
- FOXN3 | c.842G>T p.R281L (on ENST00000261302; = p.R259L on NM_005197.4) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.518); catalogued as COSV54310151; called by muse, mutect2, varscan2
- FPR2 | c.285G>T p.W95C | Missense Mutation (SNP) | VAF 75/191 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.183); catalogued as COSV60674246, COSV99077951; called by muse, mutect2, varscan2
- GAB3 | c.1342+1G>T p.X448_splice | Splice Site (SNP) | VAF 56/129 reads (43%) | catalogued as COSV65820569; called by muse, mutect2, varscan2
- GAB4 | c.1561C>A p.L521M | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68754982; called by muse, mutect2, varscan2
- GATAD2B | c.751G>T p.A251S | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.039); catalogued as COSV64085685; called by muse, mutect2, varscan2
- GFRAL | c.308A>G p.N103S | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV61234596; called by muse, mutect2, varscan2
- GGTLC1 | c.116A>T p.H39L | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53850016; called by muse, mutect2, varscan2
- GLUL | c.32A>G p.K11R | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.208); catalogued as COSV59383135; called by muse, mutect2, varscan2
- GMEB2 | c.607G>T p.A203S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.074); catalogued as COSV104382656, COSV99823340; called by muse, mutect2, varscan2
- GPR153 | c.785T>C p.L262P | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100928418; called by muse, mutect2, varscan2
- GPRC6A | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | catalogued as COSV59955456; called by muse, mutect2, varscan2
- GRIN3A | c.810C>G p.C270W | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV62457397; called by muse, mutect2, varscan2
- GTF2E2 | c.559del p.D187Tfs*6 | Frame Shift Del (DEL) | VAF 18/58 reads (31%) | catalogued as CM164272; called by mutect2, pindel, varscan2
- GUCY2F | c.711C>A p.H237Q | Missense Mutation (SNP) | VAF 34/43 reads (79%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV54307326; called by muse, mutect2, varscan2
- GXYLT1 | c.649G>C p.D217H | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55132396, COSV55135714, COSV55141721; called by muse, mutect2, varscan2
- GZMA | c.130G>T p.V44F | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57114179; called by muse, mutect2, varscan2
- HLA-DOA | c.102C>A p.Y34* | Nonsense Mutation (SNP) | VAF 20/47 reads (43%) | catalogued as COSV57714104, COSV57715463; called by muse, mutect2, varscan2
- HTR6 | c.460G>T p.A154S | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.92); catalogued as COSV57034401; called by muse, mutect2, varscan2
- ICE1 | c.6374G>T p.C2125F | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV56830865; called by muse, mutect2, varscan2
- IDO2 | c.396C>A p.D132E (on ENST00000389060; = p.D145E on NM_194294.2) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58428484; called by muse, mutect2, varscan2
- IFT122 | c.729G>T p.R243S (on ENST00000348417 / NM_052989.3; = p.R294S on NM_052985.4) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.82); PolyPhen benign (0.015); catalogued as COSV56207228; called by muse, mutect2, varscan2
- INTS13 | c.460G>C p.V154L | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.989); catalogued as rs1345410067, COSV53905011; called by muse, mutect2, varscan2
- IPMK | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV100880182; called by muse, mutect2, varscan2
- IPMK | c.211G>T p.G71C | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as COSV100880183; called by muse, mutect2, varscan2
- IRGC | c.1218T>A p.D406E | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54985869; called by muse, mutect2, varscan2
- ITGAX | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1432461419, COSV51641845, COSV51643876; called by muse, mutect2, varscan2
- JMJD1C | c.1285A>T p.N429Y | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.158); catalogued as COSV67866710; called by muse, mutect2, varscan2
- JTB | c.101T>A p.V34E | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV55133126; called by muse, mutect2
- KCNB2 | c.2401A>T p.R801W | Missense Mutation (SNP) | VAF 37/59 reads (63%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.841); catalogued as COSV73052468; called by muse, mutect2, varscan2
- KDM6A | c.3571G>T p.G1191C | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV65044541; called by muse, mutect2, varscan2
- KDM6B | c.2881G>A p.E961K | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.332); catalogued as rs71371820, COSV54685797; called by muse, mutect2, varscan2
- KEAP1 | c.1777del p.E593Rfs*2 | Frame Shift Del (DEL) | VAF 53/91 reads (58%) | catalogued as COSV50390346, COSV50582630; called by mutect2, pindel, varscan2
- KIAA1549L | c.5332A>T p.R1778W (on ENST00000321505; = p.R2075W on NM_012194.3) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58595189; called by muse, mutect2
- KIF1A | c.2527C>A p.R843S | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV57485244, COSV57499363; called by muse, mutect2, varscan2
- KLK8 | c.686G>C p.G229A | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51591792, COSV99143854, COSV99144044; called by muse, mutect2, varscan2
- KLRC1 | c.580T>G p.F194V | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.716); catalogued as COSV61725873; called by muse, mutect2, varscan2
- KRT24 | c.1293G>C p.L431F | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1473259364, COSV52881709; called by muse, mutect2, varscan2
- KRT4 | c.1382-1G>T p.X461_splice | Splice Site (SNP) | VAF 18/37 reads (49%) | catalogued as COSV99542480; called by muse, mutect2, varscan2
- L3HYPDH | c.551A>G p.D184G | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55967699; called by muse, mutect2, varscan2
- LAD1 | c.893C>A p.S298Y | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV100943749; called by muse, mutect2, varscan2
- LAD1 | c.133G>T p.A45S | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT tolerated (0.46); PolyPhen benign (0.02); catalogued as rs765601402, COSV66213168; called by muse, mutect2, varscan2
- LCOR | c.4328G>C p.S1443T | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53718001; called by muse, mutect2, varscan2
- LDLR | c.55G>C p.A19P | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.277); catalogued as COSV99369362; called by muse, mutect2
- LDOC1 | c.408C>A p.D136E | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as COSV100983116; called by muse, mutect2, varscan2
- LEF1 | c.722+1G>T p.X241_splice | Splice Site (SNP) | VAF 12/19 reads (63%) | catalogued as COSV54472204, COSV99489942; called by muse, mutect2
- LGALS3BP | c.1151A>T p.H384L | Missense Mutation (SNP) | VAF 37/65 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV53165885; called by muse, mutect2, varscan2
- LILRA1 | c.242G>A p.G81D | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as rs1476149258, COSV52184227; called by muse, varscan2
- LMAN1L | c.442A>T p.S148C | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV59003287; called by muse, mutect2, varscan2
- LRP1B | c.13129G>T p.D4377Y | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs150457308, COSV67191226, COSV67231460, COSV67274376; called by muse, mutect2, varscan2
- LRP1B | c.11773G>T p.G3925W | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67264317; called by muse, mutect2, varscan2
- LRP1B | c.7561G>T p.G2521C | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761583016, COSV67264322; called by muse, mutect2, varscan2
- LRRC37A3 | c.3791C>T p.A1264V | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV58536915; called by muse, mutect2, varscan2
- LRRC4C | c.1744G>T p.E582* | Nonsense Mutation (SNP) | VAF 15/113 reads (13%) | catalogued as COSV99536397; called by muse, mutect2, varscan2
- LRRC4C | c.1743G>T p.M581I | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV99536401; called by muse, mutect2, varscan2
- LRRC4C | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as rs1285445870, COSV53435871; called by muse, mutect2, varscan2
- LTN1 | c.4543C>G p.H1515D | Missense Mutation (SNP) | VAF 36/286 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as COSV63735043; called by muse, mutect2, varscan2
- LVRN | c.2358A>C p.K786N | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as rs370260961; called by muse, mutect2, varscan2
- MACF1 | c.9503C>A p.S3168Y | Missense Mutation (SNP) | VAF 7/46 reads (15%) | catalogued as COSV57120627, COSV57139700; called by muse, mutect2, varscan2
- MAGEB16 | c.344A>T p.Q115L | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV67874442; called by muse, mutect2, varscan2
- MAP9 | c.569A>G p.E190G | Missense Mutation (SNP) | VAF 47/71 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV60904928; called by muse, mutect2, varscan2
- MED12L | c.5018C>T p.P1673L | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV56390843, COSV56404614; called by muse, mutect2, varscan2
- MGA | c.5951T>G p.I1984R (on ENST00000219905 / NM_001164273.1; = p.I1775R on NM_001080541.2) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.029); catalogued as COSV54961417; called by muse, mutect2, varscan2
- MGAM | c.2674A>T p.K892* | Nonsense Mutation (SNP) | VAF 15/48 reads (31%) | catalogued as COSV72075455; called by muse, mutect2, varscan2
- MTA1 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV58755799; called by muse, mutect2, varscan2
- MTCL1 | c.2567A>T p.Q856L (on ENST00000306329 / NM_001378206.1; = p.Q496L on NM_015210.4) | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.013); catalogued as COSV100092989; called by mutect2, varscan2
- MUC21 | c.1307C>G p.T436S | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.013); catalogued as COSV66221965; called by muse, mutect2
- MUC7 | c.637G>T p.A213S | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.051); catalogued as COSV59219908; called by muse, varscan2
- MYH11 | c.5309G>A p.S1770N | Missense Mutation (SNP) | VAF 35/55 reads (64%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV55566403; called by muse, mutect2, varscan2
- NADK | c.547G>A p.G183R | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100410690, COSV58276058; called by muse, mutect2, varscan2
- NCF4 | c.869C>T p.A290V | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT tolerated (0.47); PolyPhen benign (0.078); catalogued as rs929287888, COSV99956983; called by muse, mutect2, varscan2
- NEK11 | c.1700A>T p.K567M | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV67285204; called by muse, mutect2, varscan2
- NID1 | c.373G>T p.D125Y | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99936732; called by muse, mutect2, varscan2
- NLGN1 | c.661G>A p.G221S | Missense Mutation (SNP) | VAF 62/105 reads (59%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.874); catalogued as COSV64344444; called by muse, mutect2, varscan2
- NLRP12 | c.923G>T p.G308V | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.825); catalogued as COSV60753498, COSV60757017; called by muse, mutect2, varscan2
- NLRP14 | c.37T>C p.F13L | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV55071166; called by muse, mutect2, varscan2
- NLRP5 | c.2381C>T p.T794I | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as COSV66766951; called by muse, mutect2, varscan2
- NOS1AP | c.109G>T p.V37L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as CM104093, COSV62639295; called by muse, mutect2, varscan2
- NOTCH1 | c.5785G>T p.E1929* | Nonsense Mutation (SNP) | VAF 45/85 reads (53%) | catalogued as COSV53078596, COSV53084921; called by muse, mutect2, varscan2
- NR4A2 | c.976G>T p.V326F | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59895344; called by muse, mutect2, varscan2
- NRG1 | c.1441G>T p.V481L (on ENST00000405005 / NM_013964.5; = p.V486L on NM_013956.5) | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.998); catalogued as COSV55150712, COSV55163333, COSV99827476; called by muse, mutect2, varscan2
- NUP153 | c.194T>A p.V65E | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50461195; called by muse, mutect2, varscan2
- NUP214 | c.261G>T p.L87F | Missense Mutation (SNP) | VAF 39/62 reads (63%) | SIFT tolerated (0.08); PolyPhen benign (0.229); catalogued as COSV63912544; called by muse, mutect2, varscan2
- OCA2 | c.1303G>C p.V435L | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.17); PolyPhen benign (0.109); catalogued as COSV104419517, COSV62355976; called by muse, mutect2, varscan2
- OGA | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 61/95 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as rs1452507094, COSV63383028; called by muse, mutect2, varscan2
- OPTC | c.509C>A p.A170D | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); catalogued as COSV65868493; called by muse, mutect2, varscan2
- OR10V1 | c.196C>A p.L66M | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100275407; called by muse, mutect2, varscan2
- OR1J2 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 52/83 reads (63%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.29); catalogued as rs759405491, COSV58944649; called by muse, mutect2, varscan2
- OR2J2 | c.154G>T p.V52L | Missense Mutation (SNP) | VAF 36/211 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65848329; called by muse, mutect2, varscan2
- OR2L3 | c.199C>A p.L67I | Missense Mutation (SNP) | VAF 81/284 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as COSV63454673; called by muse, mutect2, varscan2
- OR2T4 | c.309G>T p.M103I | Missense Mutation (SNP) | VAF 34/249 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as COSV63544939; called by muse, mutect2
- OR4A5 | c.500G>T p.G167V | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV60524276; called by muse, mutect2, varscan2
- OR4C15 | c.1010C>A p.P337H (on ENST00000314644; = p.P283H on NM_001001920.2) | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs774055903, COSV58953325, COSV58954238, COSV58955502; called by muse, mutect2, varscan2
- OR56B1 | c.233T>C p.V78A | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as COSV57723773; called by muse, mutect2, varscan2
- OR6C6 | c.623C>A p.T208K | Missense Mutation (SNP) | VAF 38/58 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV100626386; called by muse, mutect2, varscan2
- OR9G4 | c.449T>C p.I150T | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV57249674; called by muse, mutect2, varscan2
- OSTN | c.20C>G p.A7G | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.19); catalogued as rs752379265, COSV100174084; called by muse, mutect2, varscan2
- PCDHB14 | c.142C>G p.L48V | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.157); catalogued as COSV53390733; called by muse, mutect2, varscan2
- PCLO | c.5249G>A p.G1750E | Missense Mutation (SNP) | VAF 53/177 reads (30%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.99); catalogued as COSV61620921; called by muse, mutect2, varscan2
- PCNX1 | c.1645G>A p.V549I | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs774496968, COSV53100355; called by muse, mutect2, varscan2
- PDZD7 | c.712G>T p.V238L | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100931527; called by muse, mutect2, varscan2
- PEX7 | c.715C>G p.L239V | Missense Mutation (SNP) | VAF 27/213 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.182); catalogued as COSV59251455; called by muse, mutect2, varscan2
- PGAP1 | c.2378A>G p.H793R | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV61329017; called by muse, mutect2, varscan2
- PGC | c.655G>T p.G219C | Missense Mutation (SNP) | VAF 61/131 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as COSV100729578; called by muse, mutect2, varscan2
- PIK3C2G | c.352C>T p.Q118* | Nonsense Mutation (SNP) | VAF 10/74 reads (14%) | catalogued as COSV56828826; called by muse, mutect2, varscan2
- PLCG2 | c.2075A>G p.H692R | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV100841976; called by muse, mutect2, varscan2
- PLEK | c.44G>C p.G15A | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52253594; called by muse, mutect2, varscan2
- PLEKHM1 | c.921A>T p.Q307H | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as rs1256197432, COSV69599361; called by muse, mutect2, varscan2
- PLG | c.645C>G p.H215Q | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as COSV51985540; called by muse, mutect2, varscan2
- POLI | c.1501G>T p.E501* | Nonsense Mutation (SNP) | VAF 5/10 reads (50%) | catalogued as rs371061336, COSV99470716; called by muse, mutect2
- POLN | c.1939G>C p.E647Q | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.262); catalogued as COSV67023499, COSV67027201; called by muse, mutect2, varscan2
- PREX1 | c.1975-1G>A p.X659_splice | Splice Site (SNP) | VAF 13/44 reads (30%) | catalogued as COSV64255866; called by muse, mutect2, varscan2
- PREX1 | c.382C>G p.Q128E | Missense Mutation (SNP) | VAF 34/183 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.403); catalogued as COSV64255872; called by muse, mutect2, varscan2
- PRG4 | c.2420C>A p.T807N | Missense Mutation (SNP) | VAF 41/201 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.189); catalogued as COSV63356345; called by muse, mutect2, varscan2
- PRKAA1 | c.1238G>C p.S413T | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as COSV57186075, COSV99713097; called by muse, mutect2, varscan2
- PRKCG | c.1140G>T p.K380N | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54731968; called by muse, mutect2, varscan2
- PRKD3 | c.812C>A p.P271Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99305566; called by muse, mutect2, varscan2
- PTF1A | c.106C>G p.L36V | Missense Mutation (SNP) | VAF 33/45 reads (73%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.111); catalogued as COSV100919555; called by muse, mutect2, varscan2
- PTPRC | c.2525G>T p.S842I | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61419530; called by muse, mutect2, varscan2
- PTPRT | c.2582C>A p.P861H | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.541); catalogued as COSV62011814; called by muse, mutect2, varscan2
- PZP | c.3850G>T p.V1284F | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54368594; called by muse, mutect2, varscan2
- RAET1L | c.143G>T p.R48L | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.462); catalogued as rs527453577, COSV99657666; called by muse, mutect2, varscan2
- RAG1 | c.1511A>C p.H504P | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV55027650; called by muse, mutect2, varscan2
- RAG1 | c.2291G>T p.R764L | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as CM1313160, CM153012, COSV55026538, COSV55027660; called by muse, mutect2, varscan2
- RAVER1 | c.994C>T p.Q332* | Nonsense Mutation (SNP) | VAF 8/17 reads (47%) | catalogued as COSV99532133; called by muse, mutect2, varscan2
- RB1 | c.1498A>T p.R500* | Nonsense Mutation (SNP) | VAF 8/12 reads (67%) | catalogued as CM012653, CS016048, COSV99922503; called by muse, mutect2, varscan2
- REG1B | c.186C>A p.L62= | Splice Region (SNP) | VAF 41/107 reads (38%) | catalogued as COSV59304209, COSV59307286; called by muse, mutect2, varscan2
- REG1B | c.166A>T p.T56S | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0.047); catalogued as COSV59307493; called by muse, mutect2
- RFX4 | c.467C>A p.T156K (on ENST00000392842 / NM_213594.3; = p.T62K on NM_032491.6) | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.141); catalogued as COSV57580415; called by muse, mutect2, varscan2
- RILPL1 | c.655G>T p.G219W | Missense Mutation (SNP) | VAF 74/118 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV61553564; called by muse, mutect2, varscan2
- RIPPLY3 | c.150G>T p.E50D | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV61567111; called by muse, mutect2, varscan2
- RNF19A | c.1345G>A p.V449I | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs767726348, COSV61993824; called by muse, mutect2, varscan2
- RSC1A1 | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs1275588965, COSV100197301; called by muse, mutect2, varscan2
- RYR2 | c.739G>T p.V247F | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV63708405; called by muse, mutect2, varscan2
- RYR2 | c.14417G>A p.C4806Y | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63708426; called by muse, mutect2, varscan2
- SACS | c.3803A>T p.D1268V | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV66545796; called by muse, mutect2, varscan2
- SALL1 | c.1793C>A p.P598H | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV51759107; called by muse, mutect2, varscan2
- SAMD10 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV99410976; called by muse, mutect2, varscan2
- SAMD7 | c.690A>T p.E230D | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV59420746; called by muse, mutect2, varscan2
- SARS1 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52322633; called by muse, mutect2, varscan2
- SEC22A | c.101G>C p.R34T | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.107); catalogued as COSV59373623; called by muse, mutect2, varscan2
- SELENOO | c.759G>T p.R253S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66600103; called by muse, mutect2, varscan2
- SEMA4F | c.1149G>T p.E383D | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0.038); catalogued as COSV60285028; called by muse, mutect2, varscan2
- SERINC3 | c.524A>T p.Q175L | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54858140; called by muse, mutect2, varscan2
- SERPINA3 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.052); catalogued as COSV67586050; called by muse, mutect2, varscan2
- SERPINB12 | c.28A>G p.K10E | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.492); catalogued as COSV54034685; called by muse, mutect2, varscan2
- SETX | c.993A>G p.I331M | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV56392866; called by muse, mutect2, varscan2
- SHMT2 | c.914G>T p.R305L | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as COSV61075154; called by muse, mutect2, varscan2
- SLC29A3 | c.511T>C p.C171R | Missense Mutation (SNP) | VAF 35/45 reads (78%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV64386011; called by muse, mutect2, varscan2
- SLC36A1 | c.950A>T p.N317I | Missense Mutation (SNP) | VAF 27/38 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.278); catalogued as COSV54655962; called by muse, mutect2, varscan2
- SLC46A3 | c.440T>C p.F147S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99905989; called by muse, mutect2, varscan2
- SLC4A5 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs374602113; called by muse, mutect2, varscan2
- SLC9C1 | c.1888A>T p.I630F | Missense Mutation (SNP) | VAF 84/195 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV59892171; called by muse, mutect2, varscan2
- SLC9C2 | c.2875G>T p.E959* | Nonsense Mutation (SNP) | VAF 26/102 reads (25%) | catalogued as COSV62948668; called by muse, mutect2, varscan2
- SLC9C2 | c.1504A>T p.T502S | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.265); catalogued as COSV62948673; called by muse, mutect2
- SLITRK3 | c.1666C>T p.Q556* | Nonsense Mutation (SNP) | VAF 35/55 reads (64%) | catalogued as COSV53852574; called by muse, mutect2, varscan2
- SMARCA4 | c.4738G>T p.E1580* | Nonsense Mutation (SNP) | VAF 10/17 reads (59%) | catalogued as COSV60806344; called by muse, mutect2, varscan2
- SMARCE1 | c.916G>C p.E306Q | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.188); catalogued as COSV52861709, COSV52861952; called by muse, mutect2, varscan2
- SNRNP200 | c.5861G>A p.W1954* | Nonsense Mutation (SNP) | VAF 26/68 reads (38%) | catalogued as COSV55531483; called by muse, mutect2, varscan2
- SNTG2 | c.967C>A p.L323M | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV58002234; called by muse, mutect2
- SOX5 | c.1402G>T p.E468* | Nonsense Mutation (SNP) | VAF 12/101 reads (12%) | catalogued as COSV58645433; called by muse, mutect2, varscan2
- SOX6 | c.334A>T p.M112L | Missense Mutation (SNP) | VAF 57/96 reads (59%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV57055689; called by muse, mutect2, varscan2
- SPACA3 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as rs143361724; called by muse, mutect2, varscan2
- SPAG17 | c.2419G>T p.V807F | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV60466480; called by muse, mutect2, varscan2
- SPATA2 | c.10C>G p.P4A | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.54); catalogued as COSV56868025; called by muse, mutect2, varscan2
- SPOP | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61654912; called by muse, mutect2, varscan2
- SPOP | c.223G>T p.G75W | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100753063, COSV61654496, COSV61656168; called by muse, mutect2, varscan2
- SPTA1 | c.4561C>T p.P1521S | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.867); catalogued as COSV63758068; called by muse, mutect2, varscan2
- SPTA1 | c.2039-2A>G p.X680_splice | Splice Site (SNP) | VAF 8/28 reads (29%) | catalogued as COSV63758076; called by muse, mutect2, varscan2
- SRPK1 | c.515T>G p.L172R | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60415464; called by muse, mutect2
- SSH1 | c.2077C>T p.H693Y | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV58459421; called by muse, mutect2, varscan2
- SSU72 | c.143C>A p.A48D | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); catalogued as COSV52218730; called by muse, mutect2, varscan2
- STAG3 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 166/325 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.142); catalogued as rs1272980523, COSV57934096; called by muse, mutect2, varscan2
- STAU1 | c.886C>G p.Q296E (on ENST00000371856 / NM_001319135.1; = p.Q215E on NM_004602.3) | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1337898709, COSV61462157; called by muse, mutect2
- STIM2 | c.1219G>T p.D407Y | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52842743; called by muse, mutect2, varscan2
- STX7 | c.611-1G>T p.X204_splice | Splice Site (SNP) | VAF 30/85 reads (35%) | catalogued as COSV63399250; called by muse, mutect2
- STXBP5 | c.673C>A p.L225I | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV51656908; called by muse, mutect2, varscan2
- SYCP2 | c.2365A>G p.R789G | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.294); catalogued as COSV62771757; called by muse, mutect2, varscan2
- SYT6 | c.631C>A p.L211I (on ENST00000610222 / NM_001366225.1; = p.L126I on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs748232754, COSV65775731; called by muse, mutect2, varscan2
- TAAR5 | c.927C>A p.Y309* | Nonsense Mutation (SNP) | VAF 19/49 reads (39%) | catalogued as rs144431699, COSV57799710; called by muse, mutect2, varscan2
- TAFA2 | c.148C>T p.H50Y | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV69186429; called by muse, mutect2, varscan2
- TAS2R14 | c.59G>C p.G20A | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV101113750; called by muse, mutect2, varscan2
- TBC1D10B | c.1042C>T p.R348W | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs965746380, COSV101329611; called by muse, mutect2
- TDRD5 | c.871C>A p.P291T | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as COSV54249045; called by muse, mutect2, varscan2
- TEX35 | c.370C>G p.Q124E | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs906262333, COSV51107908; called by muse, mutect2, varscan2
- TEX37 | c.185C>A p.P62H | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV57556632; called by muse, mutect2, varscan2
- TGM6 | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV52483533; called by muse, varscan2
- TMCO4 | c.1673A>T p.Q558L | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.072); catalogued as COSV53876406; called by muse, mutect2, varscan2
- TNR | c.2710G>T p.G904* | Nonsense Mutation (SNP) | VAF 20/79 reads (25%) | catalogued as COSV99686642, COSV99689544; called by muse, mutect2, varscan2
- TNR | c.2709G>T p.V903= | Splice Region (SNP) | VAF 20/79 reads (25%) | catalogued as COSV99686648; called by muse, mutect2, varscan2
- TRAM1 | c.295G>C p.E99Q | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51598079; called by muse, mutect2, varscan2
- TRDMT1 | c.885A>T p.K295N | Missense Mutation (SNP) | VAF 44/69 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58320599; called by muse, mutect2, varscan2
- TRIT1 | c.1240A>G p.I414V | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs759925090, COSV57549772; called by mutect2, varscan2
- TSSK1B | c.256G>T p.V86F | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as COSV101180895; called by muse, mutect2, varscan2
- TTBK1 | c.1208C>T p.T403I | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52495705; called by muse, mutect2
- TTC21A | c.1405T>C p.C469R | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57188878; called by muse, mutect2, varscan2
- TTK | c.1079C>A p.T360K | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.066); catalogued as COSV57886377; called by muse, mutect2, varscan2
- TTK | c.2131-1G>C p.X711_splice | Splice Site (SNP) | VAF 10/69 reads (14%) | catalogued as COSV57886385; called by muse, mutect2, varscan2
- TTN | c.82094G>A p.R27365K (on ENST00000591111; = p.R19941K on NM_003319.4) | Missense Mutation (SNP) | VAF 20/48 reads (42%) | PolyPhen benign (0.003); catalogued as COSV60288553; called by muse, mutect2, varscan2
- TTN | c.31178A>G p.K10393R (on ENST00000591111; = p.K9466R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/58 reads (40%) | PolyPhen benign (0.006); catalogued as COSV60288576; called by muse, mutect2, varscan2
- TTN | c.25426A>G p.T8476A (on ENST00000591111; = p.T7549A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/78 reads (17%) | PolyPhen benign (0.003); catalogued as rs776154251, COSV60288584; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBA3D | c.152C>A p.T51K | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV58313110; called by muse, mutect2, varscan2
- TUBA3D | c.1052T>A p.F351Y | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV58313123; called by muse, mutect2, varscan2
- TWNK | c.1022G>T p.R341L | Missense Mutation (SNP) | VAF 32/43 reads (74%) | SIFT tolerated (0.62); PolyPhen benign (0.054); catalogued as COSV52967213, COSV52971392; called by muse, mutect2, varscan2
- UBAP1 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99902695, COSV99903153; called by muse, mutect2, varscan2
- UBE3C | c.2369G>A p.G790E | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61955287; called by muse, mutect2, varscan2
- UBR4 | c.641A>G p.Q214R | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV64397437; called by muse, mutect2, varscan2
- UGGT1 | c.184T>G p.L62V | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as COSV52140579; called by muse, mutect2, varscan2
- UNC5D | c.1534C>A p.H512N | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV54827877; called by muse, mutect2, varscan2
- USP25 | c.1764+1G>A p.X588_splice | Splice Site (SNP) | VAF 17/32 reads (53%) | catalogued as COSV53489354; called by muse, mutect2, varscan2
- USP54 | c.3803G>T p.R1268M | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV60446726; called by muse, mutect2, varscan2
- UTRN | c.7885G>A p.D2629N | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV62307184; called by muse, mutect2, varscan2
- WAPL | c.493A>C p.T165P | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.102); catalogued as COSV53939263; called by muse, mutect2, varscan2
- WDCP | c.544T>G p.Y182D | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54593537; called by muse, mutect2, varscan2
- XKR7 | c.1052G>T p.C351F | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73813411; called by muse, mutect2, varscan2
- ZFP57 | c.1596C>G p.I532M | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.366); catalogued as COSV100971980, COSV65306852; called by muse, mutect2, varscan2
- ZFYVE26 | c.286G>C p.V96L | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.039); catalogued as COSV61332813; called by muse, mutect2, varscan2
- ZIM2 | c.947C>G p.T316R | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.674); catalogued as COSV104380780, COSV55644586, COSV99688339; called by muse, mutect2, varscan2
- ZNF165 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV66102615; called by muse, mutect2, varscan2
- ZNF18 | c.1219C>G p.L407V | Missense Mutation (SNP) | VAF 65/88 reads (74%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as COSV59552405; called by muse, mutect2, varscan2
- ZNF217 | c.1768G>A p.A590T | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs748890703, COSV56601225; called by muse, mutect2, varscan2
- ZNF382 | c.463A>G p.S155G | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV53091437; called by muse, mutect2, varscan2
- ZNF573 | c.940G>C p.G314R (on ENST00000536220 / NM_001172692.1; = p.G256R on NM_152360.3) | Missense Mutation (SNP) | VAF 59/131 reads (45%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.664); catalogued as rs765820623, COSV100265348; called by muse, mutect2, varscan2
- ZNF624 | c.2371A>G p.T791A | Missense Mutation (SNP) | VAF 33/48 reads (69%) | SIFT tolerated (0.91); PolyPhen benign (0.048); catalogued as COSV100256896; called by muse, mutect2, varscan2
- ZNF8 | c.1615G>A p.A539T | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.976); catalogued as COSV52188345; called by muse, mutect2, varscan2
- ACTN4 | c.736_745delinsG p.I246_T249delinsA | Splice Region (DEL) | VAF 46/269 reads (17%) | called by pindel, varscan2*
- ADAMTS15 | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.16); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- CCL14 | c.98C>T p.S33L (on ENST00000618404 / NM_032963.4; = p.S49L on NM_032962.4) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- COL11A1 | c.1207C>A p.P403T | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.202); called by muse, mutect2
- DAB2IP | c.1073_1084del p.G358_A361del (on ENST00000408936; = p.G330_A333del on NM_032552.3) | In Frame Del (DEL) | VAF 4/9 reads (44%) | called by mutect2, varscan2
- DAW1 | c.649-2A>T p.X217_splice | Splice Site (SNP) | VAF 32/120 reads (27%) | called by muse, mutect2
- EFR3A | c.728dup p.R244Sfs*9 | Frame Shift Ins (INS) | VAF 42/108 reads (39%) | called by mutect2, pindel, varscan2
- FAT2 | c.12798dup p.C4267Lfs*4 | Frame Shift Ins (INS) | VAF 43/144 reads (30%) | called by mutect2, pindel, varscan2
- IGHA2 | c.468C>A p.S156R | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- IGHV4-31 | c.58C>A p.Q20K | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- IGKV1-5 | c.88C>A p.P30T | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- KIR3DL2 | c.854C>A p.A285D | Missense Mutation (SNP) | VAF 66/241 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- NLRP7 | c.1312_1317del p.L438_G439del | In Frame Del (DEL) | VAF 8/54 reads (15%) | called by mutect2, pindel, varscan2
- PKIB | c.121_125del p.G41Lfs*21 | Frame Shift Del (DEL) | VAF 11/90 reads (12%) | called by mutect2, pindel, varscan2
- SETD4 | c.727-9_728del p.X243_splice | Splice Site (DEL) | VAF 10/35 reads (29%) | called by mutect2, pindel
- STOX1 | c.2344dup p.Y782Lfs*9 | Frame Shift Ins (INS) | VAF 11/46 reads (24%) | called by mutect2, pindel, varscan2
- SVOP | c.1594del p.R532Efs*65 | Frame Shift Del (DEL) | VAF 17/136 reads (13%) | called by mutect2, pindel, varscan2
- TRAV13-2 | c.134A>G p.Y45C | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRBV4-1 | c.199G>T p.V67F | Missense Mutation (SNP) | VAF 66/154 reads (43%) | SIFT tolerated (0.66); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- USP4 | c.2432del p.K811Sfs*32 | Frame Shift Del (DEL) | VAF 32/59 reads (54%) | called by mutect2, pindel, varscan2
- WDCP | c.1735dup p.T579Nfs*6 | Frame Shift Ins (INS) | VAF 12/90 reads (13%) | called by mutect2, pindel, varscan2
- ZC3H7A | c.2596_2598del p.C866del | In Frame Del (DEL) | VAF 19/82 reads (23%) | called by mutect2, pindel, varscan2
- ZNF26 | c.259G>T p.G87C | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- ZNF623 | c.88_98del p.S30Dfs*16 | Frame Shift Del (DEL) | VAF 16/78 reads (21%) | called by mutect2, pindel, varscan2
- ABCG5 | c.735G>T p.V245= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV53213068; called by muse, mutect2
- ADAMTS12 | c.2688G>A p.A896= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as rs201796524, COSV61275738; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3498C>A p.I1166= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV101001012; called by muse, mutect2
- ADAMTSL1 | c.3499C>T p.L1167= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV101001013; called by muse, mutect2, varscan2
- AGBL1 | c.1569T>C p.S523= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV66870256; called by muse, mutect2, varscan2
- AHNAK2 | c.3675C>A p.G1225= | Silent (SNP) | VAF 21/127 reads (17%) | catalogued as COSV60927532; called by muse, mutect2, varscan2
- AKAP12 | c.4743C>T p.H1581= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as rs374182415; called by muse, mutect2, varscan2
- ANO5 | c.1563G>A p.L521= | Silent (SNP) | VAF 30/42 reads (71%) | catalogued as rs190937193, COSV61089488; called by muse, mutect2, varscan2
- AOC3 | c.1023C>T p.L341= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as rs566178487, COSV53828449; called by muse, mutect2, varscan2
- CA13 | c.135C>T p.L45= | Silent (SNP) | VAF 64/177 reads (36%) | catalogued as rs986718918, COSV58798926; called by muse, mutect2, varscan2
- CAND1 | c.1392A>T p.V464= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV73389760; called by muse, mutect2, varscan2
- CCDC60 | c.1164C>T p.A388= | Silent (SNP) | VAF 27/38 reads (71%) | catalogued as rs1483584751, COSV59549244; called by muse, mutect2, varscan2
- CDC5L | c.567A>G p.R189= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV65176939; called by muse, mutect2, varscan2
- CDR2 | c.1014G>A p.V338= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV51677284; called by muse, mutect2, varscan2
- CEACAM18 | c.618A>T p.I206= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV67283882; called by muse, mutect2, varscan2
- CHD5 | c.468C>T p.H156= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV52423136; called by muse, mutect2, varscan2
- CHRNA1 | c.288G>A p.L96= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV53684770; called by muse, mutect2, varscan2
- CNOT1 | c.327C>A p.P109= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as COSV57778649; called by muse, mutect2, varscan2
- COG2 | c.108T>C p.C36= | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as COSV64188081; called by muse, mutect2, varscan2
- CRTAC1 | c.1971C>T p.C657= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs773387702, COSV54001784, COSV54008445; called by muse, mutect2, varscan2
- CT47A6 | c.633C>A p.P211= | Silent (SNP) | VAF 115/177 reads (65%) | catalogued as COSV70031761; called by muse, mutect2, varscan2
- DENND2D | c.30C>T p.F10= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV62959876; called by muse, mutect2, varscan2
- DOCK10 | c.6219A>T p.P2073= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV51425178; called by muse, mutect2, varscan2
- DYSF | c.618G>T p.A206= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV50541529, COSV50615609; called by muse, mutect2, varscan2
- ENPP7 | c.180C>T p.D60= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs782026581, COSV60385164; called by muse, mutect2
- FAM13C | c.219C>T p.T73= | Silent (SNP) | VAF 24/29 reads (83%) | catalogued as rs773521958, COSV53243273; called by muse, mutect2, varscan2
- FOXQ1 | c.660G>T p.A220= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV99723216; called by muse, mutect2
- FPR3 | c.525C>T p.Y175= | Silent (SNP) | VAF 67/213 reads (31%) | catalogued as COSV59331648; called by muse, mutect2, varscan2
- FRG2C | c.639G>T p.R213= | Silent (SNP) | VAF 15/110 reads (14%) | called by muse, mutect2, varscan2
- GABRA6 | c.477G>A p.R159= | Silent (SNP) | VAF 55/77 reads (71%) | catalogued as COSV50885969, COSV50891156; called by muse, mutect2, varscan2
- GIMAP6 | c.490C>A p.R164= | Silent (SNP) | VAF 89/242 reads (37%) | catalogued as COSV61034295, COSV61034561; called by muse, mutect2
- GRIN2A | c.4071C>A p.L1357= | Silent (SNP) | VAF 23/34 reads (68%) | catalogued as COSV58053487, COSV58056456; called by muse, mutect2, varscan2
- H3-4 | c.310C>T p.L104= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV100797339; called by muse, mutect2, varscan2
- HHIPL2 | c.1908A>G p.L636= | Silent (SNP) | VAF 36/103 reads (35%) | catalogued as COSV58567265; called by muse, mutect2, varscan2
- HOXB1 | c.525C>G p.P175= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV53318480; called by muse, mutect2, varscan2
- HS1BP3 | c.954G>T p.L318= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as COSV58314747; called by muse, varscan2
- IL10 | c.45G>T p.G15= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV100894686; called by muse, mutect2, varscan2
- IL4I1 | c.396G>T p.G132= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as COSV100351676; called by muse, mutect2, varscan2
- INTS6L | c.2094A>T p.P698= | Silent (SNP) | VAF 40/46 reads (87%) | catalogued as COSV66084338, COSV66085964; called by muse, mutect2, varscan2
- IPO9 | c.2925T>G p.A975= | Silent (SNP) | VAF 8/83 reads (10%) | catalogued as COSV64235515; called by muse, mutect2
- JAK3 | c.1485C>T p.P495= | Silent (SNP) | VAF 61/88 reads (69%) | catalogued as rs371588040; called by muse, mutect2, varscan2
- KCNH7 | c.996T>A p.I332= | Silent (SNP) | VAF 45/100 reads (45%) | catalogued as COSV59810358; called by muse, mutect2, varscan2
- KDM6B | c.2982G>C p.V994= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV54685806; called by muse, mutect2, varscan2
- KDM6B | c.3309G>C p.L1103= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as COSV54680133, COSV54685862; called by muse, mutect2, varscan2
- KIAA1217 | c.1269A>G p.A423= | Silent (SNP) | VAF 22/34 reads (65%) | catalogued as rs933152140, COSV56822135; called by muse, mutect2, varscan2
- LACTB2 | c.603A>C p.P201= | Silent (SNP) | VAF 23/41 reads (56%) | catalogued as COSV52568436, COSV52569370; called by muse, mutect2, varscan2
- LDLR | c.54G>C p.A18= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as COSV99369361; called by muse, mutect2
- LNPEP | c.486A>T p.P162= | Silent (SNP) | VAF 57/78 reads (73%) | catalogued as COSV51480641; called by muse, mutect2, varscan2
- LRFN2 | c.1309C>T p.L437= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV57833284; called by muse, mutect2, varscan2
- LRRC7 | c.1176C>A p.S392= (on ENST00000651989 / NM_001370785.2; = p.S359= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as COSV50594369; called by muse, mutect2, varscan2
- MBTPS2 | c.1491C>T p.I497= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as COSV65269891; called by muse, mutect2, varscan2
- MDN1 | c.10188C>T p.A3396= | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as rs779317346, COSV65528746; called by muse, mutect2, varscan2
- MED12L | c.5019G>T p.P1673= | Silent (SNP) | VAF 27/53 reads (51%) | catalogued as rs765736163, COSV56374198, COSV99850822; called by muse, mutect2, varscan2
- MYB | c.1473C>T p.P491= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as rs1394512266, COSV57200994; called by muse, mutect2, varscan2
- MYH4 | c.813A>G p.L271= | Silent (SNP) | VAF 44/60 reads (73%) | catalogued as COSV55124664; called by muse, mutect2, varscan2
- MYOM2 | c.774G>T p.S258= | Silent (SNP) | VAF 34/140 reads (24%) | catalogued as COSV50759445; called by muse, mutect2, varscan2
- NNMT | c.150C>T p.C50= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV55474774; called by muse, mutect2
- OR10R2 | c.450G>T p.L150= | Silent (SNP) | VAF 57/202 reads (28%) | catalogued as COSV63769394; called by muse, mutect2, varscan2
- OR14I1 | c.612G>A p.L204= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV61200648; called by muse, mutect2, varscan2
- OR1S2 | c.714C>T p.V238= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as rs371531797, COSV56920374; called by muse, mutect2, varscan2
- OR4K13 | c.405C>A p.I135= | Silent (SNP) | VAF 16/228 reads (7%) | catalogued as COSV100237902, COSV59860600; called by muse, mutect2
- PAPPA2 | c.1626G>T p.V542= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as COSV62785003; called by muse, mutect2, varscan2
- PCDH15 | c.96C>T p.C32= | Silent (SNP) | VAF 25/44 reads (57%) | catalogued as rs1474932171, COSV57378211; called by muse, mutect2, varscan2
- PDSS2 | c.735G>C p.S245= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as COSV64657159; called by muse, mutect2
- PGBD1 | c.2118A>T p.P706= | Silent (SNP) | VAF 43/125 reads (34%) | catalogued as COSV52555674; called by muse, mutect2, varscan2
- PIF1 | c.1770C>T p.G590= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as COSV51424319; called by muse, mutect2, varscan2
- PLCL2 | c.1161A>G p.K387= (on ENST00000615277 / NM_001144382.2; = p.K261= on NM_015184.5) | Silent (SNP) | VAF 27/51 reads (53%) | catalogued as COSV67624648; called by muse, mutect2, varscan2
- POLR2A | c.1353T>C p.C451= | Silent (SNP) | VAF 90/124 reads (73%) | catalogued as COSV59495346; called by muse, mutect2, varscan2
- POLR2E | c.15G>A p.E5= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as rs1318826891, COSV53125148; called by muse, mutect2, varscan2
- POTEE | c.2860C>A p.R954= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as rs761248193; called by mutect2, varscan2
- PXDNL | c.2220C>T p.P740= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as rs767742515, COSV62496656; called by muse, mutect2, varscan2
- RYR2 | c.6081G>T p.G2027= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV100772111, COSV63708415; called by muse, mutect2, varscan2
- SCN11A | c.3867A>T p.V1289= | Silent (SNP) | VAF 30/46 reads (65%) | catalogued as COSV56576701; called by muse, mutect2, varscan2
- SCN9A | c.1173T>C p.F391= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV57621401; called by muse, mutect2, varscan2
- SDK2 | c.2202G>A p.G734= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV66194686; called by muse, mutect2
- SETDB1 | c.2913T>G p.P971= | Silent (SNP) | VAF 11/101 reads (11%) | catalogued as COSV54991098; called by muse, mutect2, varscan2
- SIM1 | c.1989G>A p.S663= | Silent (SNP) | VAF 28/126 reads (22%) | catalogued as rs151274826; ClinVar: likely benign; called by muse, mutect2, varscan2
- SKAP1 | c.949C>A p.R317= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV61151637; called by muse, mutect2, varscan2
- SPTA1 | c.3018G>C p.L1006= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV63750654, COSV63758072; called by muse, mutect2, varscan2
- STAB2 | c.132A>C p.R44= | Silent (SNP) | VAF 16/97 reads (16%) | catalogued as COSV66345525; called by muse, mutect2, varscan2
- TARS1 | c.849G>C p.T283= | Silent (SNP) | VAF 34/126 reads (27%) | catalogued as COSV54311874, COSV99466203; called by muse, mutect2, varscan2
- TMPRSS11B | c.564A>C p.G188= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV104409365, COSV60293670; called by muse, mutect2, varscan2
- TPH2 | c.300G>T p.R100= | Silent (SNP) | VAF 36/71 reads (51%) | catalogued as COSV61592724, COSV61593860; called by muse, mutect2, varscan2
- TRAV16 | c.240T>G p.A80= | Silent (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
- TUBB2B | c.657C>T p.T219= | Silent (SNP) | VAF 21/132 reads (16%) | catalogued as COSV99455195; called by muse, mutect2, varscan2
- USH1C | c.1401C>A p.A467= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV99139186; called by muse, mutect2, varscan2
- ZC3H18 | c.2337C>G p.P779= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as COSV56327502; called by muse, mutect2, varscan2
- ZNF208 | c.3300T>A p.L1100= | Silent (SNP) | VAF 60/92 reads (65%) | catalogued as COSV68111533; called by muse, mutect2, varscan2
- ZNF235 | c.720T>C p.D240= | Silent (SNP) | VAF 32/77 reads (42%) | catalogued as rs774042451, COSV52158230; called by muse, mutect2, varscan2
- ZNF638 | c.1389T>C p.D463= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV52495107; called by muse, mutect2, varscan2
- ZP4 | c.1254C>T p.S418= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV63913227; called by muse, mutect2, varscan2
- CPLANE1 | c.*4204T>G | 3'UTR (SNP) | VAF 8/83 reads (10%) | catalogued as COSV57071438; called by muse, mutect2
- GCNT2 | c.926-34775C>T | Intron (SNP) | VAF 17/101 reads (17%) | catalogued as COSV99398930; called by muse, mutect2, varscan2
- HTR4 | c.1077-1067A>G | Intron (SNP) | VAF 24/39 reads (62%) | catalogued as COSV100086807; called by muse, mutect2, varscan2
- NECTIN2 | c.1043-3606G>A | Intron (SNP) | VAF 23/57 reads (40%) | catalogued as rs752527232, COSV99374699; called by muse, mutect2, varscan2
- OR52A4P | n.678dup | RNA (INS) | VAF 29/65 reads (45%) | called by mutect2, pindel, varscan2
- PIK3CD | c.-138+2518T>C | Intron (SNP) | VAF 21/59 reads (36%) | catalogued as COSV66098842; called by muse, mutect2, varscan2
- PRR12 | c.51+513G>T | Intron (SNP) | VAF 36/118 reads (31%) | catalogued as COSV69819793; called by muse, mutect2, varscan2
- RNF213 | c.3024+160G>A | Intron (SNP) | VAF 10/44 reads (23%) | catalogued as COSV60628865; called by muse, mutect2, varscan2
- TUBB7P | n.479C>T | RNA (SNP) | VAF 17/33 reads (52%) | called by muse, mutect2, varscan2
- TUBB7P | n.478C>A | RNA (SNP) | VAF 16/32 reads (50%) | called by muse, mutect2, varscan2
- ZNF423 | c.40+33065_40+33079del | Intron (DEL) | VAF 19/44 reads (43%) | called by mutect2, pindel, varscan2
